Gene-level copy-number profile of tumor specimen ALCH-B36T-TTP1-A from ALCHEMIST case ALCH-B36T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,197 days).
Specimen ALCH-B36T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0de8c55e-116a-4f4c-a2ae-034c71ce314c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B36T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/f944c137-50b8-44bb-a4ab-23b3b5469d12

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 12,704; copy number 2: 35,656; copy number 3: 7,799; copy number 4: 2,154; copy number 5: 19; copy number 6: 4; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr8:12,676,035–12,676,389, 1 gene: AC068587.1.
- chr8:15,688,914–15,689,562, 1 gene (within-gene range 0–1): AC100850.1.
- chr11:46,376,402–46,386,608, 3 genes (within-gene range 0–2): MIR4688, MDK, CHRM4.
- chr12:164,664–182,399, 2 genes (within-gene range 0–1): AC026369.2, AC007406.3.
- chr12:193,036–194,130, 1 gene (within-gene range 0–2): AC007406.1.
- chr12:28,505,394–28,505,528, 1 gene (within-gene range 0–2): RNA5SP355.
- chr12:51,817,899–51,820,150, 1 gene: AC068987.3.
- chr13:28,778,224–28,778,937, 2 genes: AL359741.1, POM121L13P.
- chr15:64,151,715–64,163,022, 2 genes: SNX22, PPIB.
- chr16:58,083,068–58,092,947, 2 genes: Y_RNA, AC012182.1.
- chr17:16,391,434–16,492,193, 10 genes: FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:18,950,345–19,022,595, 4 genes (within-gene range 0–1): SLC5A10, AC090286.1, FAM83G, AC090286.4.
- chr19:11,435,284–11,529,172, 9 genes (within-gene range 0–1): PRKCSH, ELAVL3, AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1.
- chr19:54,415,219–54,439,544, 5 genes: TTYH1, AC245884.1, AC245884.9, AC245884.10, AC245884.8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,668,383, 7 genes, copy number 5: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1.
- chr6:35,573,585–35,728,583, 5 genes, copy number 5: FKBP5, AL033519.2, AL033519.5, AL033519.1, MIR5690.
- chr7:63,326,674–63,359,306, 7 genes, copy number 5: AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr7:63,449,819–63,456,687, 1 gene, copy number 7: ZNF734P.
- chr8:98,102,344–98,117,171, 1 gene, copy number 6: RIDA.
- chr22:15,282,557–15,304,556, 3 genes, copy number 6: AP000542.3, AP000542.1, AP000542.2.

Autosomal genes at a single copy (total copy number 1): 12,265. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
